Surgical pathology report (de-identified scan), TCGA case TCGA-39-5036, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5036-01A (Primary Tumor).

[page 1 of 5]
CGA-39-5036

Clinical Diagnosis & History:

LUL nodule increased in size; IB biopsy was benign. PET showed LUL nodule with moderate uptake.

Specimens Submitted:

- 1: SP: Left upper lobe nodule biopsy
- 2: SP: Level five lymph node
- 3: SP: Left upper lobe wedge lung
- 4: SP: Left level ten lymph node
- 5: SP: Left level eleven interlobar lymph node
- 6: SP: Left upper lung lobe

DIAGNOSIS:

- 1) LUNG, LEFT UPPER LOBE NODULE; BIOPSY:
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED.
- 2) LYMPH NODES, LEVEL V; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 3) LUNG, LEFT UPPER LOBE; WEDGE RESECTION:
- SQUAMOUS CELL CARCINOMA, MODERATELY TO POORLY DIFFERENTIATED/UNDIFFERENTIATED, OF LEFT UPPER LOBE.
- THE TUMOR MEASURES 2.0 X 2.0 X 1.5 CM.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE TUMOR INVOLVES THE SURFACE OF THE VISCERAL PLEURA.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: PARENCHYMAL GRANULOMAS AND SCARRING.
- 4) LYMPH NODES, LEFT LEVEL X; EXCISION:
- SIX ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR (0/6).
- 5) LYMPH NODES, LEFT LEVEL XI INTERLOBAR; EXCISION:
- THREE ANTHRACOTIC LYMPH NODES, NO TUMOR SEEN (0/3).
- 6) LUNG, LEFT UPPER LOBE; LOBECTOMY:
- NO RESIDUAL CARCINOMA SEEN.
- THE NON-NEOPLASTIC LUNG SHOWS CHRONIC BRONCHITIS AND FOCAL SCARRING.
- BRONCHIAL MARGINS ARE FREE OF TUMOR.

** Continued on next page **

[page 2 of 5]
- EIGHT LYMPH NODES, NEGATIVE FOR TUMOR (0/8).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh for frozen section consultation, labeled "Left upper lobe nodule biopsy" and consists of two fragments of pink-tan soft tissue ranging from 0.4 to 1.5 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

2). The specimen is received fresh for frozen section consultation, labeled "Level 5 lymph node" and consists of two anthracotic lymph nodes measuring 1.5 and 0.4 cm. The largest lymph node is bisected and the lymph nodes are entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

3). The specimen is received in formalin and is labeled "Left upper lobe wedge lung". It consists of a 7 x 6 x 2 cm wedge of lung tissue with a staple line. The pleural surface is pink tan received previously sectioned with visible, palpable nodule. The staple line is removed and serial sectioning reveals a white tan ill defined indurated tumor measuring 2 x 2 x 1.5 cm, located abutting the stapled margin, located 5 cm from the stapled margin and abutting the pleural surface. Representative submitted including the shaved staple margin.

Summary of sections:
T1 tumor near the stapled margin
T2- tumor far from stapled margin
M - margin

** Continued on next page **

[page 3 of 5]
L - uninvolved lung

4). The specimen is received in formalin, labeled "Left level ten lymph nodes" and consists of four gray tan anthracotic lymph nodes measuring from 0.4 to 1.6 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:
LN- lymph nodes

5). The specimen is received in formalin, labeled "Left level eleven interlobar lymph node" and consists of two gray tan anthracotic lymph nodes measuring 0.3 and 0.7 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:
LN- lymph nodes

6). The specimen is received fresh and is labeled, "left upper lobe lung". It consists of a 15.5 x 10.5 x 2.5 cm lung lobe with attached bronchus and blood vessels straddled by multiple staple lines, which weighs 170 gm. The attached bronchus measures 2.4 x 1.6 cm. A raw area (6.5 x 2.5 cm), exposing portion of lung parenchyma without pleural surface is noted on the posterolateral aspect, otherwise the pleural surface is smooth and glistening. The pleural surface is inked black. Two staple lines are noted, one along the inferior aspect 15.0 cm long and another peri-hilar medially 8.0 cm long. Serial sectioning reveals no definite mass grossly identified. The bronchial mucosa is smooth and glistening. Peribronchial anthracotic lymph nodes are identified ranging from 0.3 to 0.9 cm greatest dimension and submitted. The uninvolved lung parenchyma shows mild congestion and frothy fluid. Representative sections are submitted. Photographs are taken.

Summary of sections:
BM -- bronchial margin.
VM -- vascular margin.
SMI -- staple margin inferior
SMPH - staple margin perihilar
RA - random lung parenchyma at least 3 cm away from inferior aspect
RC - random lung parenchyma close to inferior aspect
LN -- lymph nodes.

Summary of Sections:
Part 1: SP: Left upper lobe nodule biopsy

** Continued on next page **

[page 4 of 5]
Block Sect. Site PCs
1 fsc 2

Part 2: SP: Level five lymph node

Block Sect. Site PCs
1 fsc 1

Part 3: SP: Left upper lobe wedge lung

Block Sect. Site PCs
5 L 5
1 M 1
4 T1 4
1 T2 1

Part 4: SP: Left level ten lymph node

Block Sect. Site PCs
2 LN 4

Part 5: SP: Left level eleven interlobar lymph node

Block Sect. Site PCs
1 LN 2

Part 6: SP: Left upper lung lobe

Block Sect. Site PCs
1 BM 1
2 LN 2
3 RA 3
3 RC 3
4 SMI 4
3 SMPH 3
1 VM 1

SPECIAL STAINS FOR ACID-FAST BACILLI (AFB) AND FUNGI (GMS) ARE NEGATIVE IN THE AREA OF PARENCHYMAL GRANULOMA.

** Continued on next page **

[page 5 of 5]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Left upper lobe nodule biopsy
NON-SMALL CELL CARCINOMA.

PERMANENT DIAGNOSIS: SAME

2. FROZEN SECTION DIAGNOSIS: SP: Level five lymph node
NEGATIVE FOR CARCINOMA.

PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file 912aa12f-c888-4440-92a0-90a63e82cc9a (TCGA-39-5036.B5F0955A-6175-4C71-AB34-639F8AC6D69A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).